Gene-level copy-number profile of tumor specimen TCGA-A2-A0CX-01A from TCGA case TCGA-A2-A0CX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.4 years (19,152 days).
Specimen TCGA-A2-A0CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.17076dfd-f38a-4894-b39e-f732f4a0823a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0CX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49497a10-a8b8-4da8-8e29-1c7384eaa2b4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 433; copy number 2: 1; copy number 3: 12,803; copy number 4: 24,119; copy number 5: 1,815; copy number 6: 12,414; copy number 7: 796; copy number 8: 155; copy number 9: 2,566; copy number 10: 3,391; copy number 11: 660; copy number 12: 432; copy number 15: 15; copy number 16: 9; copy number 17: 34; copy number 18: 2; copy number 20: 5; copy number 21: 7; copy number 22: 57; copy number 24: 27; copy number 29: 29; copy number 36: 3; copy number 48: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0CX-01A-21D-A011-01): tumor purity 0.45, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:60,677,453–61,392,838, 12 genes (within-gene range 0–6): BCAS3, RN7SL606P, AC110602.1, Y_RNA, KRT18P61, HMGN1P28, RN7SL448P, AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7,267 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,036,143–42,996,814, 38 genes, copy number 10: AL158216.1, HNRNPFP1, AC114492.1, GUCA2B, GUCA2A, FOXJ3, AC096540.1, RIMKLA, AL513331.1, ZMYND12, PPCS, CCDC30, RPS3AP11, TMSB4XP1, RNU6-536P, AL445669.1, PPIH, AC098484.4, AC098484.2, YBX1, CLDN19, P3H1, C1orf50, AC098484.3, AC098484.1, TMEM269, SVBP, ERMAP, AL512353.1, ZNF691, AL512353.2, MKRN8P, ATP6V1E1P1, SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P.
- chr1:51,724,775–75,913,242, 419 genes, copy number 10 (broad region; genes not listed).
- chr1:118,264,372–248,919,946, 2,685 genes, copy number 9–10 (broad region; genes not listed).
- chr2:94,725,674–95,149,434, 27 genes, copy number 24 (within-gene range 6–24): CNN2P11, GXYLT1P7, CNN2P8, AC073464.2, CYP4F32P, AC073464.1, SNX18P14, ANKRD20A8P, RNU6-1320P, SOWAHCP5, AC097374.1, TEKT4, MTCO1P48, MTCO3P45, RPS24P6, AC103563.3, AC103563.4, AC103563.5, AC103563.1, AC103563.6, AC103563.8, RN7SL575P, AC103563.7, MAL, AC103563.2, AC103563.9, MRPS5.
- chr3:14,602,035–27,722,711, 160 genes, copy number 11 (broad region; genes not listed).
- chr3:28,574,791–30,010,391, 1 gene, copy number 12 (within-gene range 3–12): RBMS3.
- chr3:29,390,848–30,699,576, 12 genes, copy number 9–12 (within-gene range 6–12): RPS12P5, RBMS3-AS2, MTND4LP9, RBMS3-AS1, AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2.
- chr3:36,712,422–38,825,302, 56 genes, copy number 9–12 (within-gene range 6–12): DCLK3, HSPD1P6, LINC02033, AC105749.1, TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA, UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1, AC097359.1, AC097359.3, AC097359.2, GOLGA4, TCEA1P2, RNA5SP129, C3orf35, ITGA9, RNU7-73P, ITGA9-AS1, RPL21P135, NDUFAF4P3, CTDSPL, MIR26A1, VILL, PLCD1, Y_RNA, DLEC1, PPP2R2DP1, ACAA1, Y_RNA, MYD88, OXSR1, SLC22A13, AP006193.1, SLC22A14, RNU6-235P, DLEC1P1, XYLB, ACVR2B-AS1, ACVR2B, EXOG, Y_RNA, DDTP1, RPL18AP7, SCN5A, SCN10A, AC116038.1.
- chr3:67,654,669–68,637,024, 7 genes, copy number 9 (within-gene range 3–9): SUCLG2-AS1, TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1.
- chr3:195,214,787–198,222,513, 120 genes, copy number 12 (broad region; genes not listed).
- chr5:58,198–17,955,857, 341 genes, copy number 10–15 (within-gene range 8–15) (broad region; genes not listed).
- chr5:31,093,977–45,895,970, 253 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr6:5,451,683–5,458,075, 1 gene, copy number 16: AL021328.1.
- chr6:7,268,306–7,418,037, 7 genes, copy number 21 (within-gene range 4–21): SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1.
- chr6:8,158,162–15,245,000, 101 genes, copy number 9–22 (within-gene range 4–31) (broad region; genes not listed).
- chr6:15,247,815–15,248,634, 1 gene, copy number 9: JARID2-AS1.
- chr8:57,492,884–114,791,929, 847 genes, copy number 9–16 (broad region; genes not listed).
- chr8:115,950,511–124,474,582, 121 genes, copy number 11–17 (broad region; genes not listed).
- chr8:125,091,679–128,388,636, 49 genes, copy number 11: NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1.
- chr8:130,052,104–133,409,107, 36 genes, copy number 12–17: ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6.
- chr8:135,625,185–135,742,495, 2 genes, copy number 18: MAPRE1P1, RNU1-35P.
- chr16:11,555–35,912,516, 1,419 genes, copy number 9 (broad region; genes not listed).
- chr16:64,242,608–66,493,529, 22 genes, copy number 9 (within-gene range 3–9): AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1, RNA5SP428, AC012325.1, CDH5, LINC00920, BEAN1, AC132186.1, BEAN1-AS1.
- chr17:17,972,813–20,322,973, 139 genes, copy number 9 (broad region; genes not listed).
- chr17:20,323,001–20,323,337, 2 genes, copy number 9: RNU6-467P, AC008088.1.
- chr17:29,560,547–29,707,090, 1 gene, copy number 12 (within-gene range 7–12): ABHD15-AS1.
- chr17:29,573,475–31,538,211, 94 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr17:33,013,087–34,174,964, 1 gene, copy number 12 (within-gene range 5–12): ASIC2.
- chr17:33,099,969–37,406,836, 160 genes, copy number 10–12 (within-gene range 4–12) (broad region; genes not listed).
- chr17:38,530,031–38,674,957, 3 genes, copy number 36: SRCIN1, AC006449.1, EPOP.
- chr17:39,238,466–40,017,813, 30 genes, copy number 48 (within-gene range 7–48): AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3.
- chr17:46,372,855–47,624,665, 35 genes, copy number 11–29 (within-gene range 3–29): NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11, WNT3, WNT9B, LINC01974, AC005670.1, RNU6ATAC3P, GOSR2, AC005670.2, MIR5089, RPRML, LRRC37A17P, AC005670.3, RN7SL270P, CDC27, AC002558.1, AC002558.3, AC002558.2, MYL4, ITGB3, AC068234.1, RNU7-186P, AC068234.2, THCAT158, EFCAB13, AC040934.1, MRPL45P2, NPEPPS, Y_RNA.
- chr17:58,324,472–58,415,766, 1 gene, copy number 11 (within-gene range 6–11): TSPOAP1-AS1.
- chr17:58,345,206–60,170,899, 76 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 433. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
